Somatic mutation profile of tumor specimen TCGA-CJ-4903-01A (aliquot TCGA-CJ-4903-01A-01D-1429-08) from TCGA case TCGA-CJ-4903, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 50.7 years (18,510 days).
Specimen TCGA-CJ-4903-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 296e12f6-2bf5-48b6-a6e1-8721fc423858.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4903-11A (Solid Tissue Normal), aliquot TCGA-CJ-4903-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d90fc3d-f776-45d0-83e0-9282420e209c

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 33, Silent 11, Frame Shift Del 4, Nonsense Mutation 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 145/287 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs869025655, CM1410322, CM994244, COSV56545117, COSV56548828, COSV56550478, COSV56564804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.6937C>T p.R2313* | Nonsense Mutation (SNP) | VAF 33/183 reads (18%) | catalogued as rs777113901, COSV55216486; called by muse, mutect2, varscan2
- AMBRA1 | c.1990T>C p.S664P (on ENST00000458649 / NM_001367468.1; = p.S574P on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV54055378; called by muse, mutect2
- ARFGEF2 | c.1682A>C p.K561T | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.046); catalogued as COSV64212823; called by muse, mutect2, varscan2
- ATRX | c.5707G>A p.D1903N | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs1557086166, COSV64877907; called by muse, mutect2, varscan2
- BNC1 | c.790T>C p.Y264H | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs777995282, COSV61757765; called by muse, mutect2, varscan2
- C1QTNF9 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59656964, COSV59657345; called by muse, mutect2, varscan2
- CDH18 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV56928073, COSV99939313; called by muse, mutect2, varscan2
- CYP46A1 | c.1236C>A p.N412K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV55894955; called by muse, mutect2, varscan2
- DST | c.6034G>A p.D2012N | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746717062, COSV55019181; called by muse, mutect2, varscan2
- EDC3 | c.1211T>A p.V404E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59340645; called by muse, mutect2, varscan2
- F11R | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs553706719, COSV57038051; called by muse, mutect2, varscan2
- FAM160A2 | c.2576C>T p.S859F (on ENST00000449352 / NM_001098794.2; = p.S873F on NM_032127.4) | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56411948; called by muse, mutect2, varscan2
- KCNH2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs199473036, CM112129, COSV51173513; ClinVar: not provided; called by muse, mutect2, varscan2
- KEL | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.284); catalogued as COSV62335583; called by muse, mutect2, varscan2
- KLHL32 | c.1278G>T p.W426C | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100987260, COSV65112315; called by muse, mutect2, varscan2
- MFSD6L | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs763491881, COSV61003578; called by muse, mutect2, varscan2
- MKI67 | c.3522G>T p.M1174I | Missense Mutation (SNP) | VAF 229/580 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV64074828; called by muse, mutect2, varscan2
- MKNK2 | c.470T>A p.L157Q | Missense Mutation (SNP) | VAF 81/251 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV51732939; called by muse, mutect2, varscan2
- NRG3 | c.1781G>A p.R594K (on ENST00000404547 / NM_001370084.1; = p.R570K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV64566541; called by muse, mutect2, varscan2
- NRXN3 | c.3103G>C p.A1035P (on ENST00000335750 / NM_001330195.2; = p.A662P on NM_004796.6) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59758302; called by muse, mutect2, varscan2
- NSG1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs770129715, COSV67575161; called by muse, mutect2, varscan2
- OR4D1 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52125303; called by muse, mutect2, varscan2
- PBRM1 | c.2536G>T p.E846* | Nonsense Mutation (SNP) | VAF 45/116 reads (39%) | catalogued as COSV56262392, COSV99970445; called by muse, mutect2, varscan2
- PCNX2 | c.4902C>A p.C1634* | Nonsense Mutation (SNP) | VAF 25/144 reads (17%) | catalogued as COSV50810052; called by muse, mutect2, varscan2
- PCSK1 | c.2082C>G p.N694K | Missense Mutation (SNP) | VAF 56/374 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV60735853; called by muse, mutect2
- PLEKHH3 | c.2248C>A p.P750T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV52218002; called by muse, mutect2
- PLXNA4 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529364377, COSV58132063; called by muse, mutect2, varscan2
- POLG2 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs563195356, COSV73376913; called by muse, mutect2, varscan2
- PTPA | c.1061C>A p.P354H (on ENST00000337738 / NM_178001.2; = p.P319H on NM_021131.5) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV61235175; called by muse, mutect2, varscan2
- SAMD9 | c.2114T>C p.F705S | Missense Mutation (SNP) | VAF 136/443 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66075947; called by muse, mutect2, varscan2
- SLC6A19 | c.1166T>C p.L389P | Missense Mutation (SNP) | VAF 94/253 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58671829; called by muse, mutect2, varscan2
- SMARCA5 | c.2213G>A p.R738K | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV51644852; called by muse, mutect2, varscan2
- TLR2 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV52606684; called by muse, mutect2, varscan2
- TRAPPC2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV62896691; called by muse, mutect2, varscan2
- URB2 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV50995496; called by muse, mutect2, varscan2
- VPS25 | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53820946; called by muse, mutect2, varscan2
- DCDC1 | c.2565del p.K856Nfs*12 | Frame Shift Del (DEL) | VAF 140/448 reads (31%) | called by mutect2, pindel, varscan2
- MAPK8 | c.284_302del p.Q95Lfs*6 | Frame Shift Del (DEL) | VAF 17/148 reads (11%) | called by mutect2, pindel
- PDS5B | c.334del p.R112Dfs*3 | Frame Shift Del (DEL) | VAF 20/81 reads (25%) | called by mutect2, pindel, varscan2
- VPS13C | c.3057_3058del p.S1021Ifs*16 (on ENST00000644861 / NM_020821.3; = p.S978Ifs*16 on NM_017684.5) | Frame Shift Del (DEL) | VAF 41/146 reads (28%) | called by mutect2, pindel, varscan2
- CTSG | c.537C>T p.Y179= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs1476151995, COSV53535132; called by muse, mutect2, varscan2
- CYC1 | c.645C>T p.L215= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as COSV59643595; called by muse, mutect2, varscan2
- HIVEP3 | c.1230C>T p.N410= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as rs199930261, COSV56016608; called by muse, mutect2, varscan2
- LAMP3 | c.711T>C p.C237= | Silent (SNP) | VAF 70/201 reads (35%) | catalogued as COSV55615204; called by muse, mutect2, varscan2
- MAP1B | c.6213G>A p.K2071= | Silent (SNP) | VAF 93/281 reads (33%) | catalogued as COSV57100441; called by muse, mutect2, varscan2
- NAV2 | c.18C>A p.V6= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1355140613, COSV62324916; called by muse, mutect2, varscan2
- OR1G1 | c.357C>T p.A119= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV61030279; called by muse, mutect2, varscan2
- RAPGEF4 | c.2616C>T p.N872= | Silent (SNP) | VAF 54/177 reads (31%) | catalogued as rs759396088, COSV51393616; called by muse, mutect2, varscan2
- RAPH1 | c.2691A>T p.A897= | Silent (SNP) | VAF 78/259 reads (30%) | catalogued as COSV55585008; called by muse, mutect2, varscan2
- RBM45 | c.1305C>G p.A435= (on ENST00000616198 / NM_001365579.1; = p.A433= on NM_152945.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/217 reads (30%) | catalogued as COSV53721177, COSV53722755; called by muse, mutect2, varscan2
- WDR48 | c.303A>T p.V101= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as COSV56532471, COSV56533420; called by muse, mutect2, varscan2
